Somatic mutation profile of tumor specimen TCGA-CN-6017-01A (aliquot TCGA-CN-6017-01A-11D-1683-08) from TCGA case TCGA-CN-6017, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 55.7 years (20,358 days).
Specimen TCGA-CN-6017-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10466182-4115-418e-a9dd-ab4ef314d586.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6017-10A (Blood Derived Normal), aliquot TCGA-CN-6017-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1f83ba1-da72-4c0d-a60b-59ac2c96de6b

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK2 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99913186; called by muse, mutect2
- NCKAP1 | c.132A>G p.K44= | Silent (SNP) | VAF 6/133 reads (5%) | catalogued as COSV100720349; called by muse, mutect2
